Somatic mutation profile of tumor specimen TCGA-76-4932-01A (aliquot TCGA-76-4932-01A-01D-1486-08) from TCGA case TCGA-76-4932, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 50.5 years (18,433 days).
Specimen TCGA-76-4932-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dda1d334-aff1-48c0-b7da-8e261572fea5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-76-4932-10A (Blood Derived Normal), aliquot TCGA-76-4932-10A-01D-1486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5051a15b-c08f-43ae-8b2d-e1f41b74a5a2

The open-access MAF lists 60 somatic variants for this specimen: 43 protein-altering or splice-affecting, 17 silent.
By variant classification: Missense Mutation 39, Silent 17, Nonsense Mutation 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASB10 | c.775C>T p.R259C (on ENST00000420175 / NM_001142459.2; = p.R244C on NM_080871.4) | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.878); catalogued as rs772953406, COSV51998823; called by muse, mutect2, varscan2
- CHST13 | c.367G>A p.V123M | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60042836; called by muse, mutect2, varscan2
- CILP2 | c.1639G>A p.V547M | Missense Mutation (SNP) | VAF 75/181 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52274272, COSV99364980; called by muse, mutect2, varscan2
- CLSTN3 | c.2605C>T p.R869C | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750797901, COSV56938756; called by muse, mutect2, varscan2
- CNTN4 | c.290C>T p.T97M | Missense Mutation (SNP) | VAF 76/185 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.097); catalogued as rs780874348, COSV68583535; called by muse, mutect2, varscan2
- CNTNAP4 | c.526G>A p.G176R | Missense Mutation (SNP) | VAF 57/118 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770829025, COSV56692194; called by muse, mutect2, varscan2
- COL4A4 | c.2516C>T p.P839L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.336); catalogued as rs199562472, COSV61629546; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPSF1 | c.2378C>T p.T793I | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV58234737; called by muse, mutect2
- DOCK5 | c.4442C>T p.T1481M | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as rs746351464, COSV52407250; called by muse, mutect2, varscan2
- EDDM3A | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.313); catalogued as rs199609364, COSV58795019; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2486C>T p.S829L | Missense Mutation (SNP) | VAF 98/177 reads (55%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); catalogued as rs951686169, COSV62569495; called by muse, mutect2, varscan2
- EPHA1 | c.1474C>T p.R492W | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs756203512, COSV51973676; called by muse, mutect2, varscan2
- FSD2 | c.652A>G p.K218E | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.849); catalogued as COSV58011607; called by muse, mutect2, varscan2
- GLRA2 | c.464C>T p.S155L | Missense Mutation (SNP) | VAF 78/190 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV54337159; called by muse, mutect2, varscan2
- IFNAR2 | c.668C>T p.S223F | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs960467666, COSV59750127; called by muse, mutect2, varscan2
- KRT38 | c.1340G>A p.C447Y | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.119); catalogued as COSV55846901; called by muse, mutect2
- LANCL3 | c.202G>A p.G68S | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV66129423; called by muse, varscan2
- LELP1 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 186/320 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); catalogued as rs573106359, COSV64202277; called by muse, mutect2, varscan2
- MATN4 | c.338C>T p.T113M | Missense Mutation (SNP) | VAF 15/41 reads (37%) | PolyPhen probably damaging (1); catalogued as rs998642061, COSV59215064; called by muse, mutect2
- MFSD9 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 125/302 reads (41%) | SIFT tolerated (0.59); PolyPhen benign (0.011); catalogued as rs372925047, COSV51492718; called by muse, mutect2, varscan2
- MKRN3 | c.110C>A p.P37H | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as rs764711642, COSV58809108, COSV58811143; called by muse, mutect2, varscan2
- MORC4 | c.1008T>A p.H336Q | Missense Mutation (SNP) | VAF 188/440 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55245045; called by muse, mutect2, varscan2
- NAALAD2 | c.437A>G p.N146S | Missense Mutation (SNP) | VAF 133/339 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV58960082; called by muse, mutect2, varscan2
- NUP210L | c.2150A>G p.Y717C | Missense Mutation (SNP) | VAF 77/140 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55153341; called by muse, mutect2, varscan2
- OBSCN | c.20074G>A p.E6692K | Missense Mutation (SNP) | VAF 68/224 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs780930470, COSV62274408; called by muse, mutect2, varscan2
- OR4C16 | c.881G>A p.S294N | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58943279; called by muse, mutect2
- OSBP | c.1271A>G p.K424R | Missense Mutation (SNP) | VAF 124/291 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV55664429; called by muse, mutect2, varscan2
- PCDHA1 | c.1244G>A p.R415H | Missense Mutation (SNP) | VAF 121/294 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.949); catalogued as rs568406742, COSV100974406, COSV65375826; called by muse, mutect2, varscan2
- PCSK6 | c.2620G>A p.D874N | Missense Mutation (SNP) | VAF 57/140 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.165); catalogued as rs772698260, COSV100624495, COSV61856869; called by muse, mutect2, varscan2
- PEG10 | c.505C>T p.R169C (on ENST00000482108 / NM_001040152.2; = p.R203C on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 168/619 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.971); catalogued as COSV71788371; called by muse, mutect2, varscan2
- PEG10 | c.845C>T p.T282M (on ENST00000482108 / NM_001040152.2; = p.T316M on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV101509983; called by muse, mutect2, varscan2
- PRDM9 | c.2233G>T p.E745* | Nonsense Mutation (SNP) | VAF 79/285 reads (28%) | catalogued as rs200775234, COSV57010368, COSV57010584; called by muse, varscan2
- RIMBP2 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780052862, COSV55479375; called by muse, mutect2, varscan2
- SLC38A4 | c.1336C>T p.R446* | Nonsense Mutation (SNP) | VAF 103/250 reads (41%) | catalogued as COSV56968815; called by muse, mutect2, varscan2
- SRSF12 | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 258/622 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV71683739; called by muse, mutect2, varscan2
- THOC2 | c.3781A>T p.N1261Y | Missense Mutation (SNP) | VAF 63/148 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); catalogued as COSV55551497; called by muse, mutect2, varscan2
- TMOD2 | c.727G>C p.A243P | Missense Mutation (SNP) | VAF 103/248 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV51045714; called by muse, mutect2, varscan2
- TNFAIP8 | c.201G>T p.E67D | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as COSV57228318; called by muse, mutect2, varscan2
- ZFR2 | c.217C>T p.R73* | Nonsense Mutation (SNP) | VAF 17/40 reads (43%) | catalogued as rs770422334, COSV53596453; called by muse, mutect2, varscan2
- ZNF280B | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 117/291 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as rs775765845, COSV64528312, COSV64528706; called by muse, mutect2, varscan2
- ZNF701 | c.872A>G p.N291S (on ENST00000301093; = p.N225S on NM_018260.3) | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.495); catalogued as COSV56526230; called by muse, mutect2, varscan2
- ZYX | c.860G>A p.G287E | Missense Mutation (SNP) | VAF 179/553 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as COSV59557048; called by muse, mutect2, varscan2
- SRCAP | c.7530_7533del p.T2512Rfs*9 | Frame Shift Del (DEL) | VAF 54/136 reads (40%) | called by mutect2, pindel, varscan2
- AASDH | c.831C>G p.L277= | Silent (SNP) | VAF 28/138 reads (20%) | catalogued as COSV52708636; called by muse, mutect2, varscan2
- ANGEL2 | c.438G>A p.T146= | Silent (SNP) | VAF 130/221 reads (59%) | catalogued as rs749051875, COSV64737817; called by muse, mutect2, varscan2
- ARFGEF3 | c.2283G>A p.A761= | Silent (SNP) | VAF 60/122 reads (49%) | catalogued as rs111857517; called by muse, mutect2, varscan2
- CCDC63 | c.1023G>A p.T341= | Silent (SNP) | VAF 45/118 reads (38%) | catalogued as rs549200490, COSV57527025; called by muse, mutect2, varscan2
- CWC22 | c.2313T>C p.N771= | Silent (SNP) | VAF 126/332 reads (38%) | catalogued as COSV55430680; called by muse, mutect2, varscan2
- DEFB110 | c.183C>T p.C61= | Silent (SNP) | VAF 64/148 reads (43%) | catalogued as rs758183770, COSV67018511; called by muse, mutect2, varscan2
- FLG | c.5676C>T p.A1892= | Silent (SNP) | VAF 204/982 reads (21%) | catalogued as rs370973678; called by muse, mutect2, varscan2
- IGFBP3 | c.570C>T p.Y190= | Silent (SNP) | VAF 143/452 reads (32%) | catalogued as rs766767739, COSV51872748; called by muse, mutect2, varscan2
- LILRB2 | c.1077G>A p.A359= | Silent (SNP) | VAF 65/170 reads (38%) | catalogued as rs780207679, COSV58747161; called by muse, mutect2, varscan2
- MOV10L1 | c.3183C>T p.S1061= | Silent (SNP) | VAF 56/143 reads (39%) | catalogued as rs371398149, COSV99434303; called by muse, mutect2, varscan2
- NPR2 | c.2871C>T p.R957= | Silent (SNP) | VAF 60/173 reads (35%) | catalogued as COSV52414859; called by muse, mutect2, varscan2
- OR8H1 | c.504C>T p.C168= | Silent (SNP) | VAF 58/150 reads (39%) | catalogued as rs745373167, COSV57295118; called by muse, mutect2, varscan2
- PAX3 | c.219G>A p.S73= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV51342205; called by muse, mutect2, varscan2
- RTF2 | c.843C>G p.L281= | Silent (SNP) | VAF 88/238 reads (37%) | catalogued as COSV50127891, COSV50129998; called by muse, mutect2, varscan2
- TFPI2 | c.264G>A p.R88= | Silent (SNP) | VAF 34/116 reads (29%) | catalogued as COSV55991394; called by muse, mutect2, varscan2
- TSPEAR | c.846C>T p.D282= | Silent (SNP) | VAF 62/160 reads (39%) | catalogued as rs1039830781, COSV59952169; called by muse, mutect2, varscan2
- USPL1 | c.1938A>G p.Q646= | Silent (SNP) | VAF 51/136 reads (38%) | catalogued as COSV55001204; called by muse, mutect2, varscan2
